Somatic mutation profile of tumor specimen TCGA-PJ-A5Z9-01A (aliquot TCGA-PJ-A5Z9-01A-11D-A28G-10) from TCGA case TCGA-PJ-A5Z9, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 80.4 years (29,365 days).
Specimen TCGA-PJ-A5Z9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ebd76979-f747-4716-b622-9841062920cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-PJ-A5Z9-10A (Blood Derived Normal), aliquot TCGA-PJ-A5Z9-10A-01D-A28G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3394c4ae-0f62-4107-ba0c-c94254780d65

The open-access MAF lists 64 somatic variants for this specimen: 48 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 14, Frame Shift Del 2, Frame Shift Ins 2, Intron 1, 5'UTR 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANK3 | c.11470G>A p.V3824M | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as COSV55043922; called by muse, mutect2, varscan2
- C4A | c.2665G>A p.V889M | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV71177307; called by muse, mutect2, varscan2
- CASP8AP2 | c.2215T>C p.Y739H | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1182153834, COSV52745129; called by muse, mutect2
- CLSTN3 | c.1651G>C p.E551Q | Missense Mutation (SNP) | VAF 92/159 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56933975; called by muse, varscan2
- CSMD1 | c.9028T>C p.Y3010H (on ENST00000520002; = p.Y3009H on NM_033225.6) | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV59280780, COSV59332211; called by muse, mutect2, varscan2
- DBNDD1 | c.415C>A p.P139T (on ENST00000002501 / NM_001042610.3; = p.P159T on NM_024043.3) | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.012); catalogued as COSV50021814; called by muse, mutect2, varscan2
- DHTKD1 | c.2557T>C p.Y853H | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV53801632; called by muse, mutect2, varscan2
- DNAH2 | c.11570A>T p.H3857L | Missense Mutation (SNP) | VAF 50/91 reads (55%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV66716239; called by muse, mutect2, varscan2
- ERICH3 | c.4114G>T p.A1372S | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV58598976; called by muse, mutect2, varscan2
- FCGR2C | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 53/318 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.405); catalogued as COSV63435075; called by muse, mutect2
- GPR20 | c.235T>A p.C79S | Missense Mutation (SNP) | VAF 45/146 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.501); catalogued as COSV66683855; called by muse, mutect2, varscan2
- GPR50 | c.610G>A p.V204M | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); catalogued as rs1288793743, COSV54436783; called by muse, mutect2, varscan2
- GRIN2A | c.382C>G p.H128D | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.591); catalogued as COSV100409376, COSV58019733; called by muse, mutect2, varscan2
- IGF2BP2 | c.6G>C p.M2I | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV60482841; called by muse, mutect2, varscan2
- IRX2 | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.32); catalogued as COSV57409611, COSV57413864; called by muse, mutect2
- KDM3B | c.758A>C p.D253A | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV58687919; called by muse, mutect2, varscan2
- KRT13 | c.1026A>G p.K342= | Splice Region (SNP) | VAF 18/61 reads (30%) | catalogued as COSV55838999; called by muse, mutect2, varscan2
- KRTAP19-5 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 33/46 reads (72%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.251); catalogued as rs370535457; called by muse, mutect2, varscan2
- LRP1B | c.2333G>T p.R778I | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV101258667, COSV67185657; called by muse, mutect2, varscan2
- MATN2 | c.2259G>T p.R753S | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54706622; called by muse, mutect2, varscan2
- MSH3 | c.1154A>T p.N385I | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.176); catalogued as COSV54144637; called by muse, mutect2, varscan2
- MUC16 | c.9667A>C p.T3223P | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV67444242; called by muse, mutect2
- NBEA | c.5086G>T p.G1696C | Missense Mutation (SNP) | VAF 54/103 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.846); catalogued as COSV59759804; called by muse, mutect2, varscan2
- NEFL | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.574); catalogued as rs750960565, COSV55336210; called by muse, mutect2
- PAMR1 | c.1960C>T p.P654S (on ENST00000619888 / NM_001001991.3; = p.P671S on NM_015430.4) | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV53509530; called by muse, mutect2, varscan2
- PANK2 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs759331809, COSV57252970; called by muse, mutect2, varscan2
- PCDH11X | c.3805C>T p.R1269C | Missense Mutation (SNP) | VAF 24/743 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV53442058; called by muse, mutect2
- PDE1C | c.1460G>T p.G487V | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.881); catalogued as rs1404708041, COSV58503226; called by muse, mutect2, varscan2
- PHKA1 | c.3394C>T p.L1132F | Missense Mutation (SNP) | VAF 79/269 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV59801647; called by muse, mutect2, varscan2
- PRDM9 | c.2443A>T p.N815Y | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.21); catalogued as rs202203985, COSV57004544; called by muse, mutect2, varscan2
- REPS1 | c.1120T>A p.L374M | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.451); catalogued as rs1218429821, COSV57808723; called by muse, mutect2, varscan2
- RRP12 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV59664709; called by muse, mutect2, varscan2
- SLC22A18 | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as COSV56538890; called by muse, mutect2, varscan2
- SLC30A7 | c.795A>G p.I265M | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV63016744; called by muse, mutect2, varscan2
- SPAG5 | c.1736A>G p.D579G | Missense Mutation (SNP) | VAF 45/74 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as rs747457855, COSV58799946; called by muse, mutect2, varscan2
- SPG11 | c.7210T>A p.Y2404N | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV55990698; called by muse, mutect2, varscan2
- SYNGAP1 | c.230G>C p.S77T | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT tolerated (0.97); PolyPhen benign (0.007); catalogued as COSV53378249; called by muse, mutect2, varscan2
- TBL1X | c.1667C>T p.A556V | Missense Mutation (SNP) | VAF 73/161 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.104); catalogued as COSV54274576; called by muse, mutect2, varscan2
- TMC2 | c.1636C>G p.L546V | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.313); catalogued as COSV62649699, COSV62649822; called by muse, mutect2, varscan2
- TOPORS | c.2591G>A p.S864N | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62116117; called by muse, mutect2, varscan2
- UBA7 | c.1547T>A p.L516Q | Missense Mutation (SNP) | VAF 135/231 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61091308; called by muse, mutect2, varscan2
- ZNF354B | c.653C>T p.T218I | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs764272876, COSV59365114; called by muse, mutect2, varscan2
- ZNF516 | c.2450G>C p.G817A | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1446708122, COSV71586672; called by muse, mutect2, varscan2
- IGFLR1 | c.346_348del p.P116del | In Frame Del (DEL) | VAF 10/28 reads (36%) | called by mutect2, pindel
- MIA3 | c.2919del p.V974Sfs*2 | Frame Shift Del (DEL) | VAF 29/76 reads (38%) | called by mutect2, pindel, varscan2
- SLC14A1 | c.510dup p.W171Mfs*46 | Frame Shift Ins (INS) | VAF 43/125 reads (34%) | called by mutect2, pindel, varscan2
- SREBF2 | c.2309del p.F770Sfs*8 | Frame Shift Del (DEL) | VAF 22/71 reads (31%) | called by mutect2, pindel, varscan2
- VAPB | c.240dup p.N81Qfs*2 | Frame Shift Ins (INS) | VAF 18/78 reads (23%) | called by mutect2, pindel, varscan2
- ABCA4 | c.954C>T p.I318= | Silent (SNP) | VAF 28/91 reads (31%) | catalogued as COSV64670953; called by muse, mutect2, varscan2
- ACTR8 | c.288A>G p.G96= | Silent (SNP) | VAF 66/110 reads (60%) | catalogued as COSV51635078; called by muse, varscan2
- ELAVL1 | c.291C>T p.R97= | Silent (SNP) | VAF 32/175 reads (18%) | catalogued as COSV60965754; called by muse, mutect2, varscan2
- FSIP1 | c.501G>A p.E167= | Silent (SNP) | VAF 46/113 reads (41%) | catalogued as COSV63223323; called by muse, mutect2, varscan2
- IRF2BP2 | c.1587C>T p.F529= | Silent (SNP) | VAF 35/91 reads (38%) | catalogued as COSV64014496, COSV64014555; called by muse, mutect2, varscan2
- MARS1 | c.1242G>C p.R414= | Silent (SNP) | VAF 40/172 reads (23%) | catalogued as COSV56252364; called by muse, mutect2, varscan2
- MMRN2 | c.846C>T p.A282= | Silent (SNP) | VAF 37/82 reads (45%) | catalogued as COSV64400362; called by muse, mutect2, varscan2
- NDUFAF1 | c.189C>T p.H63= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV52974720; called by muse, mutect2, varscan2
- NIPAL1 | c.906T>C p.N302= | Silent (SNP) | VAF 60/142 reads (42%) | catalogued as COSV55005719; called by muse, mutect2, varscan2
- RNF25 | c.9G>C p.A3= | Silent (SNP) | VAF 140/222 reads (63%) | catalogued as COSV55305943; called by muse, varscan2
- SLC35D1 | c.123G>T p.L41= | Silent (SNP) | VAF 32/103 reads (31%) | catalogued as COSV52429720; called by muse, mutect2, varscan2
- TEKT2 | c.675C>T p.N225= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV52880258; called by muse, mutect2, varscan2
- TICRR | c.3780G>A p.T1260= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs778508504, COSV51537753; called by muse, mutect2, varscan2
- USP33 | c.858A>G p.E286= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV62468230; called by muse, varscan2
- ARL3 | c.-1G>A | 5'UTR (SNP) | VAF 34/110 reads (31%) | catalogued as COSV99588987; called by muse, varscan2
- GMPPB | c.951+28G>A | Intron (SNP) | VAF 62/102 reads (61%) | catalogued as rs71324991, COSV57537486; called by muse, mutect2, varscan2
